Somatic mutation profile of tumor specimen MP2PRT-PARSRU-TBP1-A (aliquot MP2PRT-PARSRU-TBP1-A-1-0-D-A834-36) from MP2PRT case MP2PRT-PARSRU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.9 years (1,054 days).
Specimen MP2PRT-PARSRU-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9217fd91-044c-4b7e-93de-95a3bf72a8b9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARSRU-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARSRU-NB1-A-1-0-D-A834-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4a7bd045-51e9-4dcf-9680-f4273a48be24

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 2, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FADS3 | c.718G>A p.V240I | Missense Mutation (SNP) | VAF 116/285 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.014); catalogued as rs542548263; called by muse, mutect2, varscan2
- LPL | c.248C>T p.T83M | Missense Mutation (SNP) | VAF 107/470 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs372267210, COSV60933307; called by muse, varscan2
- PTPRD | c.4210+1G>A p.X1404_splice | Splice Site (SNP) | VAF 94/205 reads (46%) | catalogued as COSV100648181; called by muse, mutect2, varscan2
- SCN10A | c.2094G>T p.Q698H | Missense Mutation (SNP) | VAF 111/219 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.106); catalogued as COSV71862273; called by mutect2, varscan2
- SMIM10 | c.95C>T p.P32L | Missense Mutation (SNP) | VAF 422/1393 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV57707216; called by muse, mutect2, varscan2
- STXBP5 | c.335C>T p.A112V | Missense Mutation (SNP) | VAF 30/340 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs1229999216; called by muse, mutect2
- USP1 | c.2009G>A p.G670E | Missense Mutation (SNP) | VAF 85/215 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51998352; called by muse, mutect2, varscan2
- PRPF4B | c.811T>G p.S271A | Missense Mutation (SNP) | VAF 115/449 reads (26%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRDM2 | c.3666C>T p.H1222= | Silent (SNP) | VAF 194/463 reads (42%) | catalogued as rs753358984; called by muse, mutect2, varscan2
- ZNF84 | c.834C>T p.L278= | Silent (SNP) | VAF 179/427 reads (42%) | called by muse, mutect2, varscan2
- DLG2 | c.1978+3739G>A | Intron (SNP) | VAF 152/404 reads (38%) | catalogued as rs552807665; called by muse, varscan2
